National Lung Screening Trial (NLST) participant 201465 — screening results, CT findings and lung cancer
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 60 years; Gender: female; Race: White; Cigarette smoking status at randomisation: former smoker (to be eligible, former smokers had quit within the previous 15 years); Enrolled through an American College of Radiology Imaging Network (ACRIN) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 0): Positive, change unspecified: nodule(s) >= 4 mm or enlarging nodule(s), mass(es), or other non-specific abnormalities suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 50 effective mAs, display field of view 28 cm, reconstruction filter Phillips C.
- T1: No screening result: Not Expected - Cancer before screening window.
- T2: No screening result: Not Expected - Death before screening window.

Abnormalities recorded by the reading radiologist on the CT screens (6 abnormalities; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left lower lobe; longest diameter 22 mm, longest perpendicular diameter 18 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 68; new (not pre-existing on earlier images).
- T0 abnormality 2: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left lower lobe; longest diameter 20 mm, longest perpendicular diameter 17 mm; margins spiculated (stellate); predominant attenuation soft tissue; greatest diameter on CT slice 70; new (not pre-existing on earlier images).
- T0 abnormality 3: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right middle lobe; longest diameter 14 mm, longest perpendicular diameter 14 mm; margins spiculated (stellate); predominant attenuation soft tissue; greatest diameter on CT slice 74; new (not pre-existing on earlier images).
- T0 abnormality 4: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T0 abnormality 5: Benign lung nodule(s) (benign calcification).
- T0 abnormality 6: Non-calcified hilar/mediastinal adenopathy or mass (>= 10 mm on short axis).

Lung cancer (1 primary lung cancer record; the first confirmed lung cancer followed a positive screen; study year of the first confirmed lung cancer: T0; the diagnosis is linked to a positive screen through the trial's diagnostic-procedure linking algorithm)
1. First primary lung cancer, diagnosed day 96, study year T0. Site: lower lobe of lung (ICD-O-3 C34.3), determined from histology. Primary tumour location: left lower lobe. Histology: adenocarcinoma, NOS (ICD-O-3 8140/3). Tumour size on pathology: 22 mm. AJCC 6th edition staging: stage IV (best stage, from a mixture of clinical and pathologic TNM components); clinical T4 N3 M1 (stage IV); pathologic TX N3 M1 (stage IV). AJCC 7th edition staging: stage IV; clinical T3 N3 M1a; pathologic TX NX MX. Summary stage: distant.

Follow-up
Last known free of lung cancer: day 96 (for ACRIN participants with lung cancer this field holds the diagnosis date).
